TARGET case TARGET-00-RO02652 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/0695ee17-0125-4a24-be1e-e23795ad2315

Biospecimens (1 sample)
- Sample TARGET-00-RO02652-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
